Somatic mutation profile of tumor specimen 0DOV9S from CCDI case PBCCZW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.1 years (417 days).
Specimen 0DOV9S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38bc7e89-4c1f-4ff5-af6e-9ab04f31dcee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0994537-ba15-43a3-b134-6fa926bb7002

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UBA7 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 110/390 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs751480579, COSV100339676; called by muse, mutect2, varscan2
- ANKRD1 | c.210C>A p.L70= | Splice Region (SNP) | VAF 29/492 reads (6%) | called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 29/844 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
